Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8DL, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8DL-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma, tubular
8211/3
Site: Cardia NOS
C16.0
JW 11/21/13

Collect date:

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Cardia)

I-"Stomach + standardized lymphadenectomy with celiac trunk":

Gastric adenocarcinoma:

Extent of the tumor at its greatest diameter: 6.0 cm.

Ulceration present.

Histological pattern: tubular (intestinal of Lauren's classification).

Histologic grade 2.

Infiltration of mucosa, submucosa, muscularis propria and perivisceral fat.

Spiculated pattern of infiltration.

Extension to the esophageal mucosa.

Neural infiltration not detected.

Lymphatic vascular invasion not detected.

Blood vascular invasion not detected.

Surgical margins without neoplastic involvement.

Lymph nodes without neoplastic involvement (total 0/27 - see below).

Lymph nodes of greater curvature: uninvolved: 0/15

Lymph nodes of greater curvature: uninvolved 0/4

II-"11B chain lymph nodes": uninvolved 0/2

III-"8A chain lymph nodes": uninvolved 0/2

IV-"12 A chain lymph nodes": uninvolved 0/2

VI-"111 lymph nodes": uninvolved 0/2

V-"Esophageal margin":

Surgical margins without neoplastic involvement.

Criteria	No
HPA Discrepancy	☒

Source: NCI Genomic Data Commons file 80290b78-a8a5-4b99-b1fb-3c3c6b54fa26 (TCGA-VQ-A8DL.738B95E9-007A-4267-B1A3-01DE65FBCB08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).